Somatic mutation profile of tumor specimen TCGA-CM-5868-01A (aliquot TCGA-CM-5868-01A-01D-1650-10) from TCGA case TCGA-CM-5868, project TCGA-COAD (Colon Adenocarcinoma). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Sigmoid colon; AJCC pathologic stage: Stage IVA; Age at diagnosis: 59.3 years (21,672 days).
Specimen TCGA-CM-5868-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 248652a8-2ec8-43e4-949c-4b141de58fdc.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-CM-5868-10A (Blood Derived Normal), aliquot TCGA-CM-5868-10A-01D-1650-10; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/aa3f9607-5275-4077-a7c2-2d1a0ee133fd

The open-access MAF lists 104 somatic variants for this specimen: 69 protein-altering or splice-affecting, 34 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 57, Silent 34, Nonsense Mutation 5, Frame Shift Del 3, Splice Region 2, Frame Shift Ins 1, Splice Site 1, RNA 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.844C>T p.R282W | Missense Mutation (SNP) | VAF 44/75 reads (59%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs28934574, CM056413, CM920678, COSV52662048, COSV52662222, COSV52701296; ClinVar: pathogenic / likely pathogenic; called by muse, mutect2, varscan2
- AC004922.1 | c.896C>T p.A299V | Missense Mutation (SNP) | VAF 18/80 reads (23%) | SIFT deleterious (0.02); PolyPhen benign (0.354); catalogued as COSV53557415; called by muse, mutect2, varscan2
- ANGEL1 | c.1960T>G p.S654A | Missense Mutation (SNP) | VAF 12/48 reads (25%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV51873722; called by muse, mutect2, varscan2
- AOC1 | c.997G>A p.G333R | Missense Mutation (SNP) | VAF 7/29 reads (24%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs757908154, COSV62869086; called by muse, mutect2, varscan2
- APC | c.3121C>T p.Q1041* | Nonsense Mutation (SNP) | VAF 126/195 reads (65%) | catalogued as CM920045, COSV57346121, COSV57364346; called by muse, mutect2, varscan2
- ATRX | c.2899A>T p.K967* | Nonsense Mutation (SNP) | VAF 157/1091 reads (14%) | catalogued as COSV64877893; called by muse, mutect2, varscan2
- CCDC74B | c.847T>C p.W283R | Missense Mutation (SNP) | VAF 54/300 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV100134420; called by muse, mutect2
- CD109 | c.1162A>G p.N388D | Missense Mutation (SNP) | VAF 43/185 reads (23%) | SIFT tolerated (0.55); PolyPhen benign (0.001); catalogued as COSV54650617; called by muse, mutect2, varscan2
- CHRND | c.1190G>A p.S397N | Missense Mutation (SNP) | VAF 38/88 reads (43%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51320613; called by muse, mutect2, varscan2
- CNBD1 | c.87A>T p.P29= | Splice Region (SNP) | VAF 31/338 reads (9%) | catalogued as COSV72917099; called by muse, mutect2
- CRIM1 | c.749-2A>G p.X250_splice | Splice Site (SNP) | VAF 46/149 reads (31%) | catalogued as COSV54865602; called by muse, mutect2
- CWF19L2 | c.1552C>T p.Q518* | Nonsense Mutation (SNP) | VAF 58/390 reads (15%) | catalogued as COSV56513717; called by muse, mutect2, varscan2
- DCAF1 | c.127G>T p.E43* | Nonsense Mutation (SNP) | VAF 52/141 reads (37%) | catalogued as COSV60042512; called by muse, mutect2, varscan2
- DHX57 | c.593G>T p.R198L | Missense Mutation (SNP) | VAF 28/154 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.129); catalogued as COSV54886293; called by muse, mutect2, varscan2
- DMP1 | c.1040C>A p.S347* | Nonsense Mutation (SNP) | VAF 35/154 reads (23%) | catalogued as COSV56818415, COSV56820391; called by muse, mutect2, varscan2
- FANCC | c.289C>G p.L97V | Missense Mutation (SNP) | VAF 48/718 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV56661436; called by muse, mutect2
- FAT2 | c.7019A>T p.E2340V | Missense Mutation (SNP) | VAF 81/220 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV55821186; called by muse, mutect2, varscan2
- GSK3B | c.538C>T p.R180W | Missense Mutation (SNP) | VAF 48/146 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51776889; called by muse, mutect2, varscan2
- GTF2IRD2 | c.241G>A p.V81I | Missense Mutation (SNP) | VAF 40/290 reads (14%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.005); catalogued as rs781871019; called by muse, varscan2
- ISY1-RAB43 | c.593C>A p.A198E | Missense Mutation (SNP) | VAF 79/225 reads (35%) | SIFT tolerated (0.19); PolyPhen benign (0.015); catalogued as COSV56441259; called by muse, mutect2, varscan2
- KCNMB2 | c.549G>T p.K183N | Missense Mutation (SNP) | VAF 63/271 reads (23%) | SIFT tolerated (0.09); PolyPhen benign (0.258); catalogued as COSV64201113; called by muse, mutect2, varscan2
- KCNRG | c.454T>G p.W152G | Missense Mutation (SNP) | VAF 74/410 reads (18%) | SIFT tolerated (0.05); PolyPhen benign (0.012); catalogued as COSV100078343; called by muse, mutect2, varscan2
- KIF1A | c.2650C>T p.R884C | Missense Mutation (SNP) | VAF 11/62 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as rs760325615, COSV57491717; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- KMT2B | c.7016G>A p.R2339Q | Missense Mutation (SNP) | VAF 36/96 reads (38%) | SIFT tolerated (0.74); PolyPhen benign (0); catalogued as rs751409145, COSV55871387, COSV99719454; called by muse, mutect2, varscan2
- LRRC4 | c.1799C>T p.T600I | Missense Mutation (SNP) | VAF 203/448 reads (45%) | SIFT tolerated, low confidence (0.17); PolyPhen benign (0.135); catalogued as COSV50814399; called by muse, mutect2, varscan2
- MAMLD1 | c.1727C>T p.P576L | Missense Mutation (SNP) | VAF 22/206 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.32); catalogued as rs782062169, COSV53375898; called by muse, mutect2, varscan2
- MAP2K6 | c.550A>G p.N184D | Missense Mutation (SNP) | VAF 62/479 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV63006275; called by muse, mutect2, varscan2
- MAPK8IP3 | c.1559G>A p.R520H | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs767997804, COSV51721294; called by muse, mutect2
- MROH5 | c.3172G>A p.V1058M | Missense Mutation (SNP) | VAF 65/84 reads (77%) | SIFT deleterious (0); PolyPhen possibly damaging (0.611); catalogued as rs991046022, COSV101435975; called by muse, varscan2
- MUC16 | c.12883G>A p.E4295K | Missense Mutation (SNP) | VAF 45/102 reads (44%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0.003); catalogued as rs866967106, COSV67470836; called by muse, mutect2, varscan2
- NIPBL | c.71A>G p.N24S | Missense Mutation (SNP) | VAF 49/105 reads (47%) | SIFT tolerated (0.31); PolyPhen probably damaging (0.956); catalogued as COSV56953496; called by muse, mutect2, varscan2
- NLGN4X | c.388G>A p.A130T | Missense Mutation (SNP) | VAF 226/439 reads (51%) | SIFT tolerated (0.56); PolyPhen benign (0.086); catalogued as rs1029475096, COSV52010253; called by muse, mutect2, varscan2
- NTSR1 | c.1241G>A p.R414H | Missense Mutation (SNP) | VAF 21/107 reads (20%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.849); catalogued as rs766991609, COSV65138803; called by muse, mutect2, varscan2
- OR14I1 | c.724dup p.Q242Pfs*48 | Frame Shift Ins (INS) | VAF 35/141 reads (25%) | catalogued as rs779782058; called by mutect2, pindel, varscan2
- PCCA | c.625G>A p.A209T | Missense Mutation (SNP) | VAF 109/371 reads (29%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.679); catalogued as COSV66193046; called by muse, mutect2, varscan2
- PIGB | c.434T>G p.L145R | Missense Mutation (SNP) | VAF 40/156 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV51242150; called by muse, mutect2
- PLB1 | c.4288G>T p.V1430L | Missense Mutation (SNP) | VAF 26/150 reads (17%) | SIFT tolerated (0.27); PolyPhen benign (0.003); catalogued as COSV59827459; called by muse, mutect2, varscan2
- PLP1 | c.346A>T p.T116S | Missense Mutation (SNP) | VAF 43/478 reads (9%) | SIFT tolerated (0.37); PolyPhen possibly damaging (0.527); catalogued as COSV100393381; called by muse, mutect2
- PLSCR5 | c.730C>A p.L244I | Missense Mutation (SNP) | VAF 89/245 reads (36%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV71649071; called by muse, mutect2, varscan2
- RAB33A | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.995); catalogued as COSV99924536; called by muse, mutect2
- RNF123 | c.1627G>A p.G543R | Missense Mutation (SNP) | VAF 26/102 reads (25%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.999); catalogued as rs200547779, COSV100570627; called by muse, mutect2, varscan2
- ROBO1 | c.1072C>T p.R358C | Missense Mutation (SNP) | VAF 33/131 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs748988548, COSV101459619, COSV71395330; called by muse, mutect2, varscan2
- RSPRY1 | c.1544C>T p.A515V | Missense Mutation (SNP) | VAF 63/167 reads (38%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.718); catalogued as COSV68027806; called by muse, mutect2, varscan2
- RTL9 | c.3718T>C p.C1240R | Missense Mutation (SNP) | VAF 18/284 reads (6%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV101511674; called by muse, mutect2
- SDHA | c.1591G>A p.V531M | Missense Mutation (SNP) | VAF 77/347 reads (22%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0.371); catalogued as rs371056571, COSV53766702; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- SLC39A4 | c.94C>G p.L32V | Missense Mutation (SNP) | VAF 11/95 reads (12%) | SIFT tolerated (0.35); PolyPhen probably damaging (0.951); catalogued as COSV52779319; called by muse, mutect2, varscan2
- SLCO1A2 | c.67C>G p.L23V | Missense Mutation (SNP) | VAF 19/102 reads (19%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.718); catalogued as COSV100261327, COSV56603969; called by muse, mutect2, varscan2
- SLIT1 | c.658G>A p.D220N | Missense Mutation (SNP) | VAF 20/107 reads (19%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.946); catalogued as rs770874711, COSV56590712; called by muse, mutect2, varscan2
- SMAD4 | c.1308G>T p.K436N | Missense Mutation (SNP) | VAF 42/71 reads (59%) | SIFT deleterious (0); PolyPhen possibly damaging (0.861); catalogued as COSV61688387; called by muse, mutect2, varscan2
- SMOX | c.100T>A p.L34M | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV53865561; called by muse, mutect2, varscan2
- SPTBN2 | c.1159C>T p.R387C | Missense Mutation (SNP) | VAF 16/98 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (0.969); catalogued as rs1002318320, COSV59453548; called by muse, varscan2
- STKLD1 | c.1288G>A p.E430K | Missense Mutation (SNP) | VAF 46/61 reads (75%) | SIFT deleterious (0.04); PolyPhen benign (0.038); catalogued as COSV64241789; called by muse, mutect2, varscan2
- STPG1 | c.262A>G p.K88E (on ENST00000337248 / NM_001199013.2; = p.K41E on NM_178122.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 18/112 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.396); catalogued as COSV50220151; called by muse, mutect2
- SYCP2 | c.461G>A p.R154H | Missense Mutation (SNP) | VAF 97/863 reads (11%) | SIFT tolerated (0.05); PolyPhen benign (0.158); catalogued as rs768114400, COSV62766982; called by muse, mutect2, varscan2
- THSD4 | c.1533C>T p.Y511= | Splice Region (SNP) | VAF 9/43 reads (21%) | catalogued as rs377524437; called by muse, mutect2
- TRAF1 | c.225G>T p.E75D | Missense Mutation (SNP) | VAF 34/217 reads (16%) | SIFT tolerated (0.18); PolyPhen benign (0.1); catalogued as COSV65868607; called by muse, mutect2, varscan2
- TRIM49 | c.139C>A p.P47T | Missense Mutation (SNP) | VAF 114/702 reads (16%) | SIFT tolerated (0.38); PolyPhen benign (0.055); catalogued as COSV61670217; called by muse, mutect2, varscan2
- TTN | c.2422C>T p.R808C (on ENST00000591111; = p.R762C on NM_003319.4) | Missense Mutation (SNP) | VAF 86/218 reads (39%) | PolyPhen possibly damaging (0.862); catalogued as rs149155733; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- TTYH1 | c.514G>A p.A172T | Missense Mutation (SNP) | VAF 10/34 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.007); catalogued as rs1043754346, COSV56611057; called by muse, varscan2
- ZBED8 | c.1058T>A p.F353Y | Missense Mutation (SNP) | VAF 19/114 reads (17%) | SIFT deleterious (0.01); PolyPhen benign (0.316); catalogued as COSV68824780; called by muse, mutect2, varscan2
- ZNF107 | c.611C>A p.T204N | Missense Mutation (SNP) | VAF 5/58 reads (9%) | SIFT tolerated (0.19); PolyPhen benign (0); catalogued as COSV61329246; called by muse, mutect2
- ZNF354B | c.476A>C p.K159T | Missense Mutation (SNP) | VAF 12/314 reads (4%) | SIFT tolerated (0.19); PolyPhen benign (0.012); catalogued as COSV100482985; called by muse, mutect2
- ZNF414 | c.542G>A p.C181Y | Missense Mutation (SNP) | VAF 5/15 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as COSV99726537; called by muse, mutect2, varscan2
- ZNF583 | c.1556C>T p.P519L | Missense Mutation (SNP) | VAF 43/108 reads (40%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV52402890; called by muse, mutect2, varscan2
- ZNF623 | c.794G>T p.C265F | Missense Mutation (SNP) | VAF 43/133 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV71697215; called by muse, mutect2, varscan2
- KDM2B | c.85_88del p.V29Yfs*77 | Frame Shift Del (DEL) | VAF 128/326 reads (39%) | called by mutect2, pindel, varscan2
- REV1 | c.3235del p.T1079Pfs*12 | Frame Shift Del (DEL) | VAF 117/335 reads (35%) | called by mutect2, pindel, varscan2
- VN1R5 | c.968C>T p.A323V | Missense Mutation (SNP) | VAF 122/283 reads (43%) | SIFT deleterious (0); PolyPhen benign (0.034); called by muse, mutect2, varscan2
- ZNF418 | c.1193_1194del p.Y398* | Frame Shift Del (DEL) | VAF 28/182 reads (15%) | called by mutect2, pindel, varscan2
- ALK | c.1830G>A p.Q610= | Silent (SNP) | VAF 41/123 reads (33%) | catalogued as COSV66571455; called by muse, mutect2, varscan2
- ANKRD11 | c.732C>T p.N244= | Silent (SNP) | VAF 48/129 reads (37%) | catalogued as rs377170434; called by muse, mutect2, varscan2
- ANKRD17 | c.3282C>T p.G1094= | Silent (SNP) | VAF 140/620 reads (23%) | catalogued as COSV100429036; called by muse, varscan2
- ARHGAP12 | c.984T>A p.S328= | Silent (SNP) | VAF 40/165 reads (24%) | catalogued as COSV60963865; called by muse, mutect2, varscan2
- CACNA1B | c.5208C>T p.Y1736= | Silent (SNP) | VAF 14/88 reads (16%) | catalogued as rs201271068; called by muse, mutect2, varscan2
- CHD6 | c.4143C>T p.S1381= | Silent (SNP) | VAF 60/132 reads (45%) | catalogued as rs1327466022, COSV64691525; called by muse, mutect2, varscan2
- COPG1 | c.1749G>A p.T583= | Silent (SNP) | VAF 11/65 reads (17%) | catalogued as rs1441233859, COSV59114535; called by muse, mutect2
- CTNNBL1 | c.243A>G p.S81= | Silent (SNP) | VAF 91/182 reads (50%) | catalogued as COSV63745202; called by muse, mutect2, varscan2
- DAP3 | c.1068T>C p.C356= | Silent (SNP) | VAF 31/194 reads (16%) | catalogued as rs555635865, COSV100546473; called by muse, mutect2, varscan2
- EEF1A2 | c.24C>T p.I8= | Silent (SNP) | VAF 24/338 reads (7%) | catalogued as COSV53207042, COSV99419357; called by muse, mutect2
- ETNK1 | c.1086T>C p.P362= | Silent (SNP) | VAF 49/298 reads (16%) | catalogued as COSV56886285; called by muse, mutect2
- FAM180A | c.231C>T p.D77= | Silent (SNP) | VAF 22/79 reads (28%) | catalogued as rs771371356, COSV58528652; called by muse, mutect2, varscan2
- FAM234B | c.234C>A p.T78= | Silent (SNP) | VAF 29/75 reads (39%) | catalogued as COSV52195037; called by muse, mutect2, varscan2
- FBXW10 | c.715A>C p.R239= | Silent (SNP) | VAF 53/292 reads (18%) | catalogued as COSV57318237; called by muse, mutect2, varscan2
- FGF12 | c.168C>T p.S56= | Silent (SNP) | VAF 25/103 reads (24%) | catalogued as COSV53168807; called by muse, mutect2, varscan2
- FKBP9 | c.1014C>T p.H338= | Silent (SNP) | VAF 40/126 reads (32%) | catalogued as COSV54231532; called by muse, mutect2, varscan2
- GAB2 | c.855C>T p.S285= (on ENST00000361507 / NM_080491.3; = p.S247= on NM_012296.3) | Silent (SNP) | VAF 30/107 reads (28%) | catalogued as rs755736799, COSV60868497; called by muse, mutect2, varscan2
- GPR4 | c.1077G>A p.P359= | Silent (SNP) | VAF 29/136 reads (21%) | catalogued as rs139283755; called by muse, mutect2, varscan2
- H2BC4 | c.27C>A p.P9= | Silent (SNP) | VAF 97/198 reads (49%) | catalogued as COSV58415526, COSV58416434; called by muse, mutect2, varscan2
- KAT2A | c.2415C>T p.R805= | Silent (SNP) | VAF 7/26 reads (27%) | catalogued as rs200570403, COSV52426253; called by muse, mutect2, varscan2
- KRTAP10-12 | c.126C>T p.C42= | Silent (SNP) | VAF 43/118 reads (36%) | catalogued as rs782216574, COSV59951920; called by muse, mutect2, varscan2
- L1CAM | c.2721C>T p.S907= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs200799618, COSV62828463; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- MXRA5 | c.5598C>A p.T1866= | Silent (SNP) | VAF 225/471 reads (48%) | catalogued as COSV54237983; called by muse, mutect2, varscan2
- OR4D10 | c.27A>C p.V9= | Silent (SNP) | VAF 64/147 reads (44%) | catalogued as COSV73260049; called by muse, mutect2, varscan2
- PCDHA2 | c.1353C>T p.N451= | Silent (SNP) | VAF 36/147 reads (24%) | catalogued as rs376199248; called by muse, mutect2, varscan2
- PLPPR4 | c.1521C>T p.G507= | Silent (SNP) | VAF 24/102 reads (24%) | catalogued as rs916220419, COSV64564738; called by muse, mutect2, varscan2
- PLXND1 | c.3705G>A p.S1235= | Silent (SNP) | VAF 40/165 reads (24%) | catalogued as rs762034293, COSV60710845, COSV60719044; called by muse, mutect2, varscan2
- RAPGEF5 | c.1581C>T p.I527= (on ENST00000401957 / NM_001367602.2; = p.I830= on NM_012294.5) | Silent (SNP) | VAF 78/157 reads (50%) | catalogued as rs763409889, COSV59782931; called by muse, mutect2, varscan2
- S1PR5 | c.822C>T p.D274= | Silent (SNP) | VAF 24/63 reads (38%) | catalogued as COSV61013939; called by muse, mutect2, varscan2
- SLC22A6 | c.1566G>A p.R522= | Silent (SNP) | VAF 60/152 reads (39%) | catalogued as COSV64560316; called by muse, mutect2, varscan2
- TAS2R10 | c.772C>T p.L258= | Silent (SNP) | VAF 63/294 reads (21%) | catalogued as COSV53701155; called by muse, mutect2, varscan2
- ZDBF2 | c.1440T>A p.I480= | Silent (SNP) | VAF 36/165 reads (22%) | catalogued as COSV100984730; called by muse, mutect2, varscan2
- ZDHHC9 | c.717C>T p.V239= | Silent (SNP) | VAF 46/106 reads (43%) | catalogued as rs1401761833, COSV64096200, COSV64097455; called by muse, mutect2, varscan2
- ZFHX3 | c.5970G>A p.K1990= | Silent (SNP) | VAF 75/211 reads (36%) | catalogued as COSV51721337; called by muse, mutect2, varscan2
- MIR506 | n.117G>A | RNA (SNP) | VAF 143/324 reads (44%) | catalogued as rs782357814; called by muse, mutect2, varscan2
